Somatic mutation profile of tumor specimen RC-B65O-TBP1-A (aliquot RC-B65O-TBP1-A-1-0-D-A93N-47) from RC case RC-B65O, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 65.5 years (23,927 days).
Specimen RC-B65O-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04b48a80-df5d-4250-a84b-d8530a87976e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65O-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65O-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb3d9bdf-9657-4cf9-a2bf-5b36af79ca74

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA1 | c.7279A>C p.N2427H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRT | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZIM3 | c.865A>C p.R289= | Silent (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
